TCGA case TCGA-FS-A1ZR — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: Essen. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f4dde50-fa0c-43bf-8d5d-70b76cc35793

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 36 years; Vital status: Dead; Days to death: 347 days.

Diagnoses (4)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: Progression; Age at diagnosis: 36.7 years (13,404 days); Days to diagnosis: 79 days; Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Trunk.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 36.5 years (13,325 days); Year of diagnosis: 1995; AJCC staging edition: 4th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 3 of this record; Age at diagnosis: 36.9 years (13,477 days); Days to diagnosis: 152 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 152 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 347 days; Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FS-A1ZR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 100 mg.
  Slide TCGA-FS-A1ZR-06A-02-TSB: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 65; Percent normal cells: 65; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FS-A1ZR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 2; Radiation therapy to primary: No; Primary location: Regional Cutaneous or Subcutaneous Tissue (includes satellite and in-transit metastasis); Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 347 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 347 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 152 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FS-A1ZR-06A-21D-A191-01): tumor purity 0.81, ploidy 1.95, whole-genome doublings 0.
